Surgical pathology report (de-identified scan), TCGA case TCGA-43-2578, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-2578-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Left upper lobe
- B. Level 2 node
- C. Level 11 node
- D. Level 5 node
- E. Level 9 node
- F. Level 7 node
- G. Level 10 node

CLINICAL NOTES

PRE-OP DIAGNOSIS: Hilar mass.

GROSS DESCRIPTION

A. Received fresh for tissue procurement, subsequently fixed in formalin labeled "left upper lobe" is a 21 x 8 x 4.5 cm lobe of lung, which is particularly covered with red violaceous and glistening pleura showing black stippling present. One surface of the pleura is inked black on the hilar side and its opposite side of the pleura is inked blue. The specimen is sectioned to show a pink-red spongy cut surface with a 1.8 x 1.5 x 1.4 cm tan-white, firm mass which grossly does not involve the pleural surfaces. The mass is within 0.1 cm of the pleural surface (pleural surface opposite of hilar side) and comes within 4 cm of the hilum. The remainder of the specimen is sectioned to show a pink-red spongy cut surface. A few hilar nodes are grossly identified. Representative sections of specimen are submitted as follows:

BLOCK SUMMARY: 1-3 - Entire lesion to pleura, 4 - representative normal and apical aspect, 5 - representative bronchial and vascular margins, 6-7 - possible lymphoid tissue at hilum. RS-7.

B. Received fresh, subsequently fixed in formalin labeled "level 12 node" is a 1.5 x 1.2 x 0.5 cm pink-gray irregular

GROSS DESCRIPTION

soft tissue fragment, which is bisected to show a gray-black cut surface. The specimen is entirely submitted in one cassette. AS-1

C. Received fresh, subsequently fixed in formalin labeled "level 11 node" are two pink-gray irregular rubbery tissue fragments, which are 1.2 cm and 0.3 cm in greatest dimension. The specimens are entirely submitted in one cassette. AS-1

D. Received fresh, subsequently fixed in formalin labeled "level 5 node" is a 2.2 x 1.5 x 1.2 cm gray-pink irregular

[page 2 of 3]
rubbery tissue fragment, which is bisected to show a gray-black cut surface. The specimen is bisected and entirely submitted in one cassette. AS-1

E. Received fresh, subsequently fixed in formalin labeled "level 9 node" is a 1.2 x 0.5 x 0.3 cm yellow-black irregular rubbery tissue fragment, which is entirely submitted in one cassette. AS-1

F. Received fresh, subsequently fixed in formalin labeled "level 7 node" is a 1.2 x 1 x 0.3 cm pink-gray irregular soft tissue fragment, which is entirely submitted in one cassette. AS-1

G. Received fresh, subsequently fixed in formalin labeled "level 10 node" are multiple black-gray irregular tissue fragments, which are friable, having an aggregate measurement of 2

x

1.2 x 0.3. Specimens are entirely submitted in one cassette. AS-1

MICROSCOPIC DESCRIPTION

Histologic type: Non-small cell carcinoma, with squamous features.

Histologic grade: Moderately-differentiated

Primary tumor: pT1 (carcinoma is 1.8 cm in greatest dimension, without involvement of main bronchus)

Margins of resection: Negative

MICROSCOPIC DESCRIPTION

Direct extension of tumor: Not identified

Venous/arterial (large vessel) invasion: Negative

Lymphatic (small vessel) invasion: Negative

Regional lymph nodes (pN):

Three negative hilar lymph nodes (0/3).

One negative level 12 lymph node (0/1).

Two negative level 11 lymph nodes (0/2).

One negative level 5 lymph node (0/1).

One negative level 9 lymph node (0/1).

One negative level 7 lymph node (0/1).

One negative level 10 lymph node (0/1).

[page 3 of 3]
DIAGNOSIS

- A. Lung, left upper lobe, lobectomy:
- Non-small-cell carcinoma, moderately-differentiated, with squamous features.
- Size: 1.8 cm in greatest dimension.
- Margins of excision: negative.
- Angiolymphatic invasion: not identified.
- Three negative hilar lymph nodes (0/3).
- B. Lymph node, level 12, biopsy:
- One negative lymph node (0/1).
- C. Lymph node, level 11, biopsy:
- Two negative lymph nodes (0/2).
- D. Lymph node, level 5, biopsy:
- One negative lymph node (0/1).
- E. Lymph node, level 9, biopsy:
- One negative lymph node (0/1).
- F. Lymph node, level 7, biopsy:
- One negative lymph node (0/1).
- G. Lymph node, level 10, biopsy:

DIAGNOSIS

One negative lymph node (0/1).

Source: NCI Genomic Data Commons file f9723add-b4c9-439e-afb9-160975616ae7 (TCGA-43-2578.EBD86E31-D68F-404B-AD7D-BDFBEE556F3B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).